Somatic mutation profile of tumor specimen MP2PRT-PATVUA-TMP1-A (aliquot MP2PRT-PATVUA-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PATVUA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (956 days).
Specimen MP2PRT-PATVUA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7460470c-b0da-449f-bc78-578624afae50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATVUA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATVUA-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c85bb073-f449-45ab-a554-95d724de9037

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.15265C>T p.R5089W | Missense Mutation (SNP) | VAF 69/557 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs770546237; called by muse, mutect2, varscan2
- ZNF18 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 223/832 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.929); catalogued as rs772979075, COSV59550877; called by muse, mutect2, varscan2
- CAMSAP2 | c.4343G>A p.R1448K (on ENST00000236925 / NM_001297707.2; = p.R1437K on NM_203459.3) | Missense Mutation (SNP) | VAF 82/195 reads (42%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- FLG | c.445G>T p.G149W | Missense Mutation (SNP) | VAF 65/184 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- TRDD3 | chr14:22449122 del TACGCACAGTGC | Missense Mutation (DEL) | VAF 4/46 reads (9%) | called by mutect2*, pindel, varscan2*
- BEX2 | c.-81-158A>G | Intron (SNP) | VAF 154/806 reads (19%) | called by muse, mutect2, varscan2
- C6orf223 | n.574G>A | RNA (SNP) | VAF 387/1205 reads (32%) | catalogued as rs1367754459, COSV100350362, COSV100350395; called by muse, mutect2, varscan2
- CHN2 | c.577-43C>T | Intron (SNP) | VAF 224/542 reads (41%) | catalogued as rs770388092; called by muse, varscan2
